Somatic mutation profile of tumor specimen TCGA-FG-A4MY-01A (aliquot TCGA-FG-A4MY-01A-11D-A26M-08) from TCGA case TCGA-FG-A4MY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Parietal lobe; Tumor grade: G2; Age at diagnosis: 44.7 years (16,310 days).
Specimen TCGA-FG-A4MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf1105d-2dd6-4224-8c53-7eddc1407ab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A4MY-10A (Blood Derived Normal), aliquot TCGA-FG-A4MY-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/873ddd5a-9a3d-4a9e-b191-ecf1c2fda667

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 25/44 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2951T>G p.I984S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59392464; called by muse, mutect2, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2, varscan2
- ALPP | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV67395773; called by muse, mutect2
- ANKRD50 | c.3751A>G p.S1251G | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV72386323; called by muse, mutect2, varscan2
- DMD | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs752767880, COSV63791356; ClinVar: benign; called by muse, mutect2, varscan2
- EIF4A1 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV51510000; called by muse, mutect2
- EIF4G1 | c.2690G>A p.G897E (on ENST00000346169 / NM_198241.3; = p.G702E on NM_004953.5) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59993820; called by muse, mutect2, varscan2
- FANCD2 | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV55046447; called by muse, mutect2, varscan2
- KIF2B | c.762C>A p.D254E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52135322; called by muse, mutect2, varscan2
- LETM1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as rs1340815089, COSV57104485; called by muse, mutect2, varscan2
- MAGEC2 | c.40A>G p.N14D | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1038333224, COSV56001532; called by muse, mutect2, varscan2
- MBNL3 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV63731671; called by muse, mutect2, varscan2
- MED12 | c.816G>T p.L272F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV61355516; called by muse, mutect2
- PAPPA | c.4696T>A p.Y1566N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60291842, COSV60294248; called by muse, mutect2
- PLEKHG1 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV62051127; called by muse, mutect2, varscan2
- PTPRJ | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV69254665; called by muse, mutect2, varscan2
- RWDD2A | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV52285996; called by muse, mutect2, varscan2
- SEMA3B | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367707188; called by muse, mutect2, varscan2
- TMEM104 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59112251; called by muse, mutect2, varscan2
- TTN | c.18864A>G p.I6288M (on ENST00000591111; = p.I5361M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | PolyPhen benign (0.339); catalogued as COSV60347866; called by muse, mutect2
- VAV2 | c.1968G>A p.P656= (on ENST00000371850 / NM_001134398.2; = p.P646= on NM_003371.4) | Splice Region (SNP) | VAF 24/88 reads (27%) | catalogued as rs150295787; called by muse, mutect2, varscan2
- ZNF625 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63241931; called by muse, mutect2
- ATRX | c.5297del p.K1766Rfs*16 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- FAF2 | c.162dup p.E55Rfs*5 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- AARS2 | c.2649G>C p.L883= | Silent (SNP) | VAF 13/220 reads (6%) | catalogued as COSV55117506; called by muse, mutect2
- PAK3 | c.180T>C p.N60= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV53280365, COSV53280640; called by muse, mutect2, varscan2
- PRKCG | c.547C>T p.L183= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV54732092; called by muse, mutect2
- TMEM187 | c.423G>C p.L141= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV64142109; called by muse, mutect2
- RN7SL484P | chr15:99791095 G>A | 5'Flank (SNP) | VAF 49/108 reads (45%) | catalogued as rs746769189; called by muse, mutect2, varscan2
